Somatic mutation profile of tumor specimen ALCH-B1VA-TTP1-A (aliquot ALCH-B1VA-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 43.3 years (15,829 days).
Specimen ALCH-B1VA-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48e6e550-d1c1-4a8b-979b-b9549ef5e805.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VA-NB1-A (Blood Derived Normal), aliquot ALCH-B1VA-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d8249e9-a45a-40c7-aac6-0e62ba87f01c

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Del 2, Splice Site 2, Intron 1, In Frame Ins 1, 3'UTR 1, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 361/869 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4283C>T p.A1428V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99782036; called by muse, mutect2, varscan2
- ATG13 | c.69+1G>T p.X23_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as COSV56320418; called by muse, mutect2, varscan2
- CHD8 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1011766590; called by muse, mutect2
- HDAC10 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762501392, COSV99352554; called by muse, mutect2, varscan2
- LMAN1L | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs1422595434; called by muse, mutect2, varscan2
- MORC3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV68689278; called by muse, mutect2, varscan2
- PCDHGA1 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65295584; called by muse, mutect2, varscan2
- RBFOX2 | c.1325G>A p.R442Q (on ENST00000438146 / NM_001349995.2; = p.E355K on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1038642382; called by muse, mutect2, varscan2
- TDRD12 | c.2981C>T p.P994L (on ENST00000444215; = p.P999L on NM_001366102.1) | Missense Mutation (SNP) | VAF 117/767 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs533446853; called by muse, mutect2, varscan2
- TRPM4 | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781722830; called by muse, mutect2, varscan2
- ADGRL3 | c.3341T>C p.M1114T (on ENST00000506720 / NM_001322402.2; = p.M1046T on NM_015236.6) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AL592490.1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CHD9 | c.7343G>A p.R2448K (on ENST00000398510 / NM_001382353.1; = p.R2432K on NM_025134.7) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ERO1A | c.1125+2T>A p.X375_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- FAM171A1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- GP1BA | c.65T>A p.V22D | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MXD3 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NAIP | c.292T>C p.F98L | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NET1 | c.1639_1642del p.V547Kfs*22 (on ENST00000355029 / NM_001047160.3; = p.V493Kfs*22 on NM_005863.5) | Frame Shift Del (DEL) | VAF 33/202 reads (16%) | called by mutect2, pindel, varscan2
- POT1 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAP1GDS1 | c.722G>A p.R241K (on ENST00000408927 / NM_001100427.2; = p.R242K on NM_021159.5) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHCG | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SETD2 | c.2197_2200del p.D733Ifs*33 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- TLN1 | c.1195_1196insGGA p.I398_I399insR | In Frame Ins (INS) | VAF 29/177 reads (16%) | called by mutect2, pindel, varscan2
- WNK1 | c.2612A>T p.Q871L | Missense Mutation (SNP) | VAF 120/521 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF813 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 78/638 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, varscan2
- ACE | c.3486G>A p.E1162= | Silent (SNP) | VAF 325/747 reads (44%) | called by muse, mutect2, varscan2
- ANKRD10 | c.873G>A p.P291= | Silent (SNP) | VAF 84/480 reads (18%) | catalogued as rs199529091; called by muse, mutect2, varscan2
- CCDC40 | c.2925C>T p.A975= | Silent (SNP) | VAF 198/436 reads (45%) | catalogued as rs776232255; called by muse, mutect2, varscan2
- DNAH17 | c.3601C>A p.R1201= | Silent (SNP) | VAF 134/296 reads (45%) | catalogued as COSV101103144; called by muse, mutect2, varscan2
- DSPP | c.567C>T p.S189= | Silent (SNP) | VAF 45/235 reads (19%) | catalogued as rs558198925; called by muse, mutect2, varscan2
- MERTK | c.2424G>A p.E808= | Silent (SNP) | VAF 154/739 reads (21%) | called by muse, mutect2, varscan2
- SMTN | c.1230C>T p.C410= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as rs1450255353; called by muse, mutect2, varscan2
- VWDE | c.417G>C p.G139= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- AL353804.4 | chrX:73822003 A>G | 5'Flank (SNP) | VAF 31/71 reads (44%) | catalogued as rs1429296928; called by muse, mutect2, varscan2
- KNOP1P1 | n.62A>C | RNA (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- LIMK1 | c.1284+18C>T | Intron (SNP) | VAF 85/407 reads (21%) | called by muse, mutect2, varscan2
- P3H4 | c.-261dup | 5'UTR (INS) | VAF 193/581 reads (33%) | called by mutect2, pindel, varscan2
- TRIM8 | c.*507_*520del | 3'UTR (DEL) | VAF 30/282 reads (11%) | called by mutect2, pindel
